Somatic mutation profile of tumor specimen ALCH-AELQ-TTP1-A (aliquot ALCH-AELQ-TTP1-A-2-0-D-A657-36) from ALCHEMIST case ALCH-AELQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.1 years (21,210 days).
Specimen ALCH-AELQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0e9d497-a52f-44c0-8ee2-d65cf8f0f169.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AELQ-NB1-A (Blood Derived Normal), aliquot ALCH-AELQ-NB1-A-2-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ef18bc8-4ae9-40f6-b8c7-513731224323

The open-access MAF lists 160 somatic variants for this specimen: 108 protein-altering or splice-affecting, 34 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 34, RNA 6, Intron 5, 5'UTR 4, Nonsense Mutation 4, Splice Region 2, 3'UTR 2, Splice Site 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 26/342 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- A1CF | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs1413676643, COSV51055694; called by muse, mutect2, varscan2
- ACAN | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV61359840; called by muse, mutect2
- BEST1 | c.1101-4C>T | Splice Region (SNP) | VAF 13/179 reads (7%) | catalogued as rs1262214021; called by muse, mutect2
- C2orf16 | c.4853C>A p.P1618H | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV62678261; called by muse, mutect2
- C7 | c.1973C>A p.S658Y | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57470115; called by muse, mutect2, varscan2
- CATSPER3 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 36/468 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs142712287, COSV99254099; called by muse, mutect2
- CILP2 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV52280433; called by muse, mutect2
- CNTN1 | c.2442A>T p.E814D | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV61642343; called by muse, mutect2
- EAPP | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV51651500; called by muse, mutect2
- ECRG4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369596728, COSV53001627; called by muse, mutect2
- EDA2R | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.22); catalogued as rs1207666953; called by muse, mutect2, varscan2
- EEF2K | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as rs780264247; called by muse, mutect2
- ENG | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as rs1287626001; called by muse, mutect2
- EPHA10 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60405173; called by muse, mutect2
- EPHB6 | c.2486C>A p.A829E | Missense Mutation (SNP) | VAF 42/602 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63890828; called by muse, mutect2
- F13A1 | c.1828A>C p.T610P | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV53562209; called by muse, mutect2
- HK3 | c.1453G>C p.E485Q | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV52839856; called by muse, mutect2
- IGHV3-15 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 41/408 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.057); catalogued as rs552580648; called by muse, mutect2
- KEAP1 | c.932A>T p.H311L | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV50274684, COSV50325697, COSV50579650; called by muse, mutect2
- KIAA2026 | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV52391881; called by muse, mutect2
- KNL1 | c.1010T>C p.I337T (on ENST00000346991 / NM_170589.5; = p.I311T on NM_144508.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1466930041; called by muse, mutect2, varscan2
- KSR2 | c.2324G>T p.G775V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56681331; called by muse, mutect2
- MAS1L | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV101009669; called by muse, mutect2
- MPPED2 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813111, COSV63901358; called by muse, mutect2
- OR2T12 | c.511G>T p.E171* | Nonsense Mutation (SNP) | VAF 20/307 reads (7%) | catalogued as COSV58775952; called by muse, mutect2
- OR4C15 | c.602C>G p.A201G (on ENST00000314644; = p.A147G on NM_001001920.2) | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV100115561, COSV100116073, COSV58951716; called by muse, mutect2
- OR8U1 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as rs748069339, COSV100163675; called by muse, mutect2
- RORB | c.929G>T p.C310F (on ENST00000396204 / NM_001365023.1; = p.C299F on NM_006914.4) | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65338347; called by muse, mutect2
- RYR2 | c.12122G>T p.G4041V | Missense Mutation (SNP) | VAF 36/523 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63662087, COSV63684418; called by muse, mutect2
- SLC44A5 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100901578, COSV63771932; called by muse, varscan2
- SOGA1 | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs975083512, COSV99413760; called by muse, mutect2, varscan2
- TAOK1 | c.1067G>C p.S356T | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1341171609; called by muse, mutect2
- TEX13C | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV100255554, COSV66047889; called by muse, mutect2
- TMC6 | c.569G>A p.R190K | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs991673617; called by muse, mutect2
- TSR1 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV52155918; called by muse, mutect2
- UGT2B17 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1437548006; called by muse, mutect2
- UNC45B | c.43C>G p.R15G | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV52102812; called by muse, mutect2
- VIL1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs377665182; called by muse, mutect2
- VWA3B | c.2474C>T p.S825L | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV101346080; called by muse, mutect2
- ABCC4 | c.1505A>T p.E502V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.589); called by muse, mutect2
- ADAMTS1 | c.919G>T p.V307L | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRL3 | c.1615T>A p.S539T (on ENST00000506720 / NM_001322402.2; = p.S471T on NM_015236.6) | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AKAP6 | c.5943G>T p.E1981D | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- ALG13 | c.1350G>T p.M450I | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ALG3 | c.326T>C p.M109T | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP5 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 13/181 reads (7%) | called by muse, mutect2
- BET1 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- CABIN1 | c.2138G>T p.R713L | Missense Mutation (SNP) | VAF 25/380 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); called by muse, mutect2
- CHD1 | c.2528G>T p.R843M | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CNR1 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 21/330 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- CPNE5 | c.1157C>G p.A386G | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2
- CR2 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); called by muse, mutect2
- CSMD1 | c.10124C>A p.T3375N (on ENST00000520002; = p.T3374N on NM_033225.6) | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- DHX35 | c.32G>T p.W11L | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- DMXL1 | c.7095T>A p.H2365Q | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- DNAH9 | c.3933G>T p.M1311I | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- DOCK5 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DSC3 | c.1077+1G>T p.X359_splice | Splice Site (SNP) | VAF 32/362 reads (9%) | called by muse, mutect2
- DTL | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM90A1 | c.574A>C p.S192R | Missense Mutation (SNP) | VAF 43/702 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2
- FLRT1 | c.1187C>G p.A396G | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.234); called by muse, mutect2
- FREM2 | c.3438A>G p.I1146M | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2
- GABRA5 | c.1047G>T p.W349C | Missense Mutation (SNP) | VAF 26/305 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2
- GPR1 | c.290T>A p.V97E | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- GPR6 | c.1019T>A p.L340Q | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- GRPR | c.1135T>C p.C379R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRPR | c.1136G>T p.C379F | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGHG1 | c.824A>T p.K275M | Missense Mutation (SNP) | VAF 45/532 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.554); called by muse, mutect2
- IL17RA | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 40/538 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2
- KDM3A | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- LIMK1 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- MALRD1 | c.3954G>T p.Q1318H | Missense Mutation (SNP) | VAF 26/287 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAT2B | c.185G>T p.R62I | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUC16 | c.34744G>T p.A11582S | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MUC19 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.892); called by muse, mutect2
- MUC2 | c.393C>A p.S131R | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- NAV2 | c.6482C>T p.T2161I (on ENST00000396087 / NM_001244963.2; = p.T2102I on NM_145117.5) | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OLFM1 | c.727G>T p.G243C (on ENST00000371793 / NM_001282611.2; = p.G225C on NM_014279.5) | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10AD1 | c.270C>A p.D90E | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- OR14A2 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- OR14A2 | c.322G>T p.G108* | Nonsense Mutation (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- OR5W2 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- OTOGL | c.5794A>T p.K1932* (on ENST00000547103; = p.K1923* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 9/135 reads (7%) | called by muse, mutect2
- P3H1 | c.1914G>T p.T638= | Splice Region (SNP) | VAF 34/390 reads (9%) | called by muse, mutect2
- PCDHB2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 26/653 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); called by muse, mutect2
- PDE3A | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 21/302 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2
- PHEX | c.398A>C p.Q133P | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PITPNM2 | c.2153A>T p.E718V | Missense Mutation (SNP) | VAF 13/212 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RASGEF1C | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBMXL3 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- RELN | c.6901C>A p.H2301N | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); called by muse, mutect2
- ROR2 | c.2665C>A p.L889M | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2
- SHCBP1 | c.1268T>G p.F423C | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC44A5 | c.1608G>T p.L536F | Missense Mutation (SNP) | VAF 29/274 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SLCO1B3 | c.339A>T p.L113F | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SLCO4A1 | c.1942C>G p.Q648E | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2
- SNTG1 | c.1457A>T p.K486M | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SPPL2A | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TENM1 | c.4673A>G p.N1558S | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- TERF2IP | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.282); called by muse, mutect2
- TMEM33 | c.329-1G>T p.X110_splice | Splice Site (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- TNIP2 | c.535C>G p.Q179E | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.444); called by muse, mutect2
- UBR2 | c.3912G>T p.M1304I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2
- VPS41 | c.702G>T p.W234C | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- WDR75 | c.822G>T p.E274D | Missense Mutation (SNP) | VAF 23/244 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.237); called by muse, mutect2
- ZFHX3 | c.1757G>T p.R586M | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ZFHX4 | c.6976G>T p.D2326Y | Missense Mutation (SNP) | VAF 17/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANK3 | c.5374C>T p.L1792= | Silent (SNP) | VAF 16/336 reads (5%) | catalogued as rs1167302579; called by muse, mutect2
- ATP2B2 | c.2784G>A p.P928= (on ENST00000352432; = p.P894= on NM_001683.5) | Silent (SNP) | VAF 24/314 reads (8%) | catalogued as rs151087332; called by muse, mutect2
- ATP6V1G2 | c.111G>A p.K37= | Silent (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- BMP5 | c.1224G>A p.L408= | Silent (SNP) | VAF 31/265 reads (12%) | catalogued as rs866931258; called by muse, mutect2, varscan2
- CD163 | c.1542T>A p.V514= | Silent (SNP) | VAF 34/325 reads (10%) | called by muse, mutect2
- CDH24 | c.843C>G p.L281= | Silent (SNP) | VAF 5/76 reads (7%) | called by muse, mutect2
- DNAH6 | c.8190G>T p.L2730= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV52849447; called by muse, mutect2
- ENPP2 | c.1344G>A p.V448= (on ENST00000075322 / NM_001040092.3; = p.V500= on NM_006209.5) | Silent (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2
- FAT4 | c.3003T>C p.Y1001= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs1295148063; called by muse, mutect2
- FEZF1 | c.540G>T p.P180= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- GBGT1 | c.936G>A p.K312= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- GORAB | c.207A>G p.P69= | Silent (SNP) | VAF 40/351 reads (11%) | called by muse, mutect2, varscan2
- LGI2 | c.1155G>A p.S385= | Silent (SNP) | VAF 19/178 reads (11%) | catalogued as rs568065563, COSV66122703; called by muse, mutect2, varscan2
- LILRB4 | c.261C>A p.S87= | Silent (SNP) | VAF 28/376 reads (7%) | catalogued as COSV54407972; called by muse, mutect2
- LRP1B | c.13317C>T p.I4439= | Silent (SNP) | VAF 24/272 reads (9%) | catalogued as COSV67269319; called by muse, mutect2
- MDM4 | c.240T>C p.L80= | Silent (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- MUC16 | c.18738C>T p.S6246= | Silent (SNP) | VAF 21/214 reads (10%) | called by muse, mutect2, varscan2
- MYO3A | c.3054C>A p.T1018= | Silent (SNP) | VAF 35/557 reads (6%) | catalogued as COSV56324499; called by muse, mutect2
- MYO3B | c.1632A>G p.Q544= | Silent (SNP) | VAF 10/163 reads (6%) | called by muse, mutect2
- OR4C13 | c.753C>T p.P251= | Silent (SNP) | VAF 17/157 reads (11%) | catalogued as rs150732180, COSV73648836, COSV73648861; called by muse, mutect2, varscan2
- OR4K17 | c.735A>T p.T245= | Silent (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2
- OR6K2 | c.354C>A p.A118= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as COSV62743425; called by muse, mutect2
- PCDHA9 | c.1260C>A p.A420= | Silent (SNP) | VAF 32/357 reads (9%) | called by muse, mutect2
- PCDHB11 | c.1302G>A p.E434= | Silent (SNP) | VAF 27/510 reads (5%) | catalogued as rs782061785, COSV61312374; called by muse, mutect2
- PSAP | c.696C>T p.R232= | Silent (SNP) | VAF 40/490 reads (8%) | called by muse, mutect2
- PTCH1 | c.3318G>T p.T1106= | Silent (SNP) | VAF 20/280 reads (7%) | called by muse, mutect2
- SCN10A | c.5088C>A p.A1696= | Silent (SNP) | VAF 17/249 reads (7%) | catalogued as COSV101479601; called by muse, mutect2
- SOS1 | c.1554A>G p.L518= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as rs765369803; ClinVar: likely benign; called by muse, mutect2
- TBRG4 | c.591G>A p.E197= | Silent (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- TNR | c.3606G>T p.G1202= | Silent (SNP) | VAF 23/217 reads (11%) | called by muse, mutect2, varscan2
- TP53TG3D | c.342C>A p.A114= | Silent (SNP) | VAF 56/942 reads (6%) | called by muse, mutect2
- TTN | c.20691C>T p.N6897= (on ENST00000591111; = p.N5970= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs752620885, COSV100617886; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, varscan2
- UPP2 | c.627C>A p.L209= | Silent (SNP) | VAF 21/224 reads (9%) | catalogued as COSV50046792, COSV50047832; called by muse, mutect2
- VCAN | c.2232C>A p.T744= | Silent (SNP) | VAF 41/498 reads (8%) | called by muse, mutect2
- AC073310.1 | n.317C>A | RNA (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
- ANKRD26P1 | n.97A>G | RNA (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- BLK | c.*361C>T | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- C14orf177 | n.495C>A | RNA (SNP) | VAF 25/363 reads (7%) | catalogued as COSV57900803; called by muse, mutect2
- C5orf66-AS2 | n.774C>A | RNA (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2
- COLEC11 | c.130+1749G>T | Intron (SNP) | VAF 23/277 reads (8%) | catalogued as rs998407012; called by muse, mutect2
- CRIP1 | c.-25C>T | 5'UTR (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- DPAGT1 | c.917+33A>G | Intron (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- EIF3IP1 | n.485G>T | RNA (SNP) | VAF 14/146 reads (10%) | catalogued as rs749224794; called by muse, mutect2, varscan2
- FCRL3 | c.*1975T>A | 3'UTR (SNP) | VAF 13/247 reads (5%) | called by muse, mutect2
- HNRNPA1 | c.15+223C>T | Intron (SNP) | VAF 18/344 reads (5%) | called by muse, mutect2
- KHDRBS3 | c.-4G>T | 5'UTR (SNP) | VAF 27/300 reads (9%) | catalogued as rs771887710; called by muse, mutect2
- L1CAM | chrX:153888564 ins A | 5'Flank (INS) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- LINC00293 | n.568C>A | RNA (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- LPCAT3 | c.151+16817G>A | Intron (SNP) | VAF 14/245 reads (6%) | called by muse, mutect2
- NFASC | c.-49G>A | 5'UTR (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- RIF1 | c.-419C>T | 5'UTR (SNP) | VAF 16/386 reads (4%) | called by muse, mutect2
- TBX22 | c.175+41C>A | Intron (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
